Somatic mutation profile of tumor specimen TCGA-DD-AACW-01A (aliquot TCGA-DD-AACW-01A-11D-A40R-10) from TCGA case TCGA-DD-AACW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 43.5 years (15,872 days).
Specimen TCGA-DD-AACW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84e3a983-f28d-40e6-921b-b34d250aff0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACW-10A (Blood Derived Normal), aliquot TCGA-DD-AACW-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5378d0c-1407-4479-a1c9-2feeeeffa6c3

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, RNA 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.4219A>G p.K1407E | Missense Mutation (SNP) | VAF 102/126 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99229866; called by muse, mutect2, varscan2
- ABHD12B | c.619G>A p.G207S (on ENST00000337334 / NM_001206673.2; = p.G130S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100485861, COSV100485879; called by muse, mutect2, varscan2
- ASTL | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs774657969, COSV60904191; called by muse, mutect2, varscan2
- AXIN1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 18/26 reads (69%) | catalogued as rs754357905, COSV51991391; called by muse, mutect2, varscan2
- C11orf80 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV100691202; called by muse, mutect2, varscan2
- CFAP61 | c.3581A>G p.E1194G | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99846979; called by muse, mutect2, varscan2
- COL6A6 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651087; called by muse, mutect2, varscan2
- COL7A1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs747699511, COSV100097989, COSV60397222; called by muse, mutect2, varscan2
- CRY2 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV101314625; called by muse, mutect2, varscan2
- ENDOD1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV99566912; called by muse, mutect2, varscan2
- FRYL | c.2270T>A p.L757H | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV99978501; called by muse, mutect2, varscan2
- HECTD1 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101237569; called by muse, mutect2, varscan2
- HS3ST1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs568292548, COSV99137084; called by muse, mutect2, varscan2
- LAMB4 | c.2629G>T p.G877W | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226036; called by muse, mutect2, varscan2
- LPA | c.5384A>G p.D1795G | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs776342497, COSV60302957; called by muse, mutect2, varscan2
- MAGEB4 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 129/151 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758990121, COSV100975143; called by muse, mutect2, varscan2
- MAPK1 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53186374; called by muse, mutect2, varscan2
- MED1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs746684915, COSV56128108; called by muse, mutect2, varscan2
- MXRA5 | c.3702C>A p.H1234Q | Missense Mutation (SNP) | VAF 102/116 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54241682, COSV99479770; called by muse, mutect2, varscan2
- NFYC | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV100438789; called by muse, mutect2, varscan2
- OSBPL10 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100824478; called by muse, mutect2, varscan2
- PAK4 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100426652; called by muse, mutect2, varscan2
- PHACTR2 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 80/97 reads (82%) | catalogued as rs781238513, COSV59849899; called by muse, mutect2, varscan2
- PIK3R1 | c.1495C>T p.Q499* (on ENST00000521381 / NM_181523.3; = p.Q229* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV99163055; called by muse, mutect2, varscan2
- PTCD3 | c.1668A>C p.K556N | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99606731; called by muse, mutect2, varscan2
- RAPGEF6 | c.3455A>C p.K1152T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as COSV99728410; called by muse, mutect2, varscan2
- SCARB1 | c.406A>C p.M136L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99909770; called by muse, mutect2, varscan2
- SMARCA2 | c.3080A>C p.E1027A | Missense Mutation (SNP) | VAF 305/423 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100571607; called by muse, mutect2, varscan2
- SOGA1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99415932; called by muse, mutect2, varscan2
- TIAM1 | c.4510A>G p.I1504V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99739707; called by muse, mutect2, varscan2
- TTN | c.3071T>C p.V1024A (on ENST00000591111; = p.V978A on NM_003319.4) | Missense Mutation (SNP) | VAF 55/143 reads (38%) | PolyPhen possibly damaging (0.737); catalogued as COSV100634878; called by muse, mutect2, varscan2
- WDR25 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1566951669, COSV58933715; called by muse, mutect2, varscan2
- ZNF222 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.791); catalogued as COSV99496677; called by muse, mutect2, varscan2
- ZNF639 | c.136A>T p.R46* | Nonsense Mutation (SNP) | VAF 142/502 reads (28%) | catalogued as COSV100418497; called by muse, mutect2, varscan2
- ATP10B | c.2126_2135del p.D709Gfs*27 | Frame Shift Del (DEL) | VAF 41/92 reads (45%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2044T>A p.F682I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- FRMD4A | c.1510_1537delinsA p.L504_A513delinsT | In Frame Del (DEL) | VAF 32/76 reads (42%) | called by pindel, varscan2*
- NLGN1 | c.867del p.Q290Nfs*4 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PTDSS1 | c.1115del p.G372Dfs*31 | Frame Shift Del (DEL) | VAF 58/168 reads (35%) | called by mutect2, pindel, varscan2
- ZNF227 | c.432dup p.Q145Sfs*4 | Frame Shift Ins (INS) | VAF 175/731 reads (24%) | called by mutect2, pindel, varscan2
- CCDC9 | c.714G>A p.E238= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs201513324, COSV99699919; called by muse, mutect2, varscan2
- DNAH11 | c.13032T>G p.T4344= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV100181387; called by muse, mutect2, varscan2
- PELO | c.105G>T p.V35= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99252346; called by muse, mutect2
- RNF213 | c.10458G>A p.E3486= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV100301705; called by muse, mutect2, varscan2
- TAS1R1 | c.345G>A p.T115= | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs375985047; called by muse, mutect2, varscan2
- TRIP12 | c.4311A>G p.L1437= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV99391078; called by muse, mutect2, varscan2
- TTLL1 | c.414G>A p.K138= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV99840614; called by muse, mutect2, varscan2
- UBAC1 | c.504G>T p.A168= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV100873836, COSV65614031; called by muse, mutect2, varscan2
- ZNF648 | c.1527C>T p.C509= | Silent (SNP) | VAF 123/206 reads (60%) | catalogued as COSV60570632; called by muse, mutect2, varscan2
- CSH1 | c.456+96G>A | Intron (SNP) | VAF 68/163 reads (42%) | catalogued as rs758589218, COSV100298488; called by muse, mutect2, varscan2
- MIR551B | n.43C>A | RNA (SNP) | VAF 64/217 reads (29%) | called by muse, mutect2, varscan2
